National Lung Screening Trial (NLST) participant 203503 — screening results and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 59 years; Gender: male; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; no CT screening exam record exists for this participant — in this public subset that is the pattern of the chest-radiography arm: every CT screen with a result has an exam record, and the subset has no trial-arm field)
- T0 (day 0): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer.
- T1 (day 372): Negative screen, significant abnormalities not suspicious for lung cancer. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality).
- T2 (day 799): Negative screen, significant abnormalities not suspicious for lung cancer. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality).

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer occurred after the screening years; study year of the first confirmed lung cancer: T5; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 1,893, study year T5. Site: lung, NOS (ICD-O-3 C34.9), determined from cytology and histology combined. Primary tumour location: right upper lobe, right middle lobe, right lower lobe, right hilum, right main stem bronchus, other location. Histology: squamous cell carcinoma, NOS (ICD-O-3 8070/3). AJCC 6th edition staging: stage IIIB (best stage, from clinical TNM); clinical T4 N2 M0 (stage IIIB); pathologic TX NX MX. AJCC 7th edition staging: stage IIIB; clinical T4 N2 M0; pathologic TX NX MX. Summary stage: regional.

Follow-up
Last known free of lung cancer: day 1,893 (for ACRIN participants with lung cancer this field holds the diagnosis date).
